Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6155, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6155-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

....

Clinical Diagnosis & History:

with rectosigmoid cancer.

Specimens Submitted:

- 1: SP: Sigmoid and upper rectum open end proximal
- 2: SP: Distal ring margin
- 3: SP: Proximal ring margin

DIAGNOSIS:

1. SP: Sigmoid and upper rectum open end proximal:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Rectosigmoid

Tumor Size:

Length is 1.5 cm

Width is 1.3 cm

Maximal thickness is 0.2 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Muscularis propria

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

4.5cm from distal resection margin

** Continued on next page **

[page 2 of 4]
1.5 cm between deepest tumor portion and deep (radial soft tissue) margin

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 3

Total number examined: 31

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC [REDACTED])

pT2 (Tumor invades muscularis propria)

Lymph Node Stage (AJCC [REDACTED])

N1b (Metastasis in 2-3 regional lymph nodes)

Comment: The results of immunohistochemical stains for mismatch repair proteins will be reported in an addendum.

2. RECTUM, DISTAL MARGIN; RESECTION:

-SEGMENT OF RECTUM WITH NO PATHOLOGIC DIAGNOSIS.

3. COLON, PROXIMAL MARGIN; RESECTION:

-SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Out ***

Gross Description:

1. The specimen is received fresh and is labeled "sigmoid and upper rectum". It consists of a rectosigmoid colon that measures 15.5 cm in length and 5.4 cm in circumference. The open end indicates the proximal margin. The serosal surface is intact and grossly unremarkable. The radial resection margin is inked black and the specimen is opened to reveal a tumor that is located 9 cm from the proximal margin and 4.5 cm from the distal margin. The tumor measures 1.5 cm in length and 1.3 cm in width. Serial sectioning reveals tumor invasion to a depth of 0.2 cm, which is 1.5 cm from the closest radial margin. The remaining mucosa is unremarkable. Pericolonic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

T - tumor

** Continued on next page **

[page 3 of 4]
U - uninvolved mucosa
LN - lymph nodes
BLN - bisected lymph node

2). The specimen is received in formalin, labeled "Distal ring margin" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.0 x 1.5 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

3). The specimen is received in formalin, labeled "Proximal ring margin" and consists of a ring of pink tan soft tissue measuring 1.7 x 1.7 x 1.1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:
Part 1: SP: Sigmoid and upper rectum open end proximal

Block	Sect.	Site	PCs
1		dm	1
7		LN	28
1		pm	1
1		rm	1
7		t	7
2		u	2

Part 2: SP: Distal ring margin

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Proximal ring margin

Block	Sect.	Site	PCs
1		U	1

Procedures/Addenda:

** Continued on next page **

[page 4 of 4]
[REDACTED]

----- Page 4 of 4

Addendum

Date Ordered: [REDACTED]

[REDACTED]

Addendum Diagnosis

Results of immunohistochemical staining for DNA mismatch repair proteins are as follows:

MLH1: Staining present in tumor
MSH2: Staining present in tumor
MSH6: Staining present in tumor
PMS2: Staining present in tumor

Conclusion: Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file bde9961d-5925-4f3a-a176-0c27f7ebfe9b (TCGA-DC-6155.09A1A795-A160-47AC-BBA2-266765CC1184.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).